Somatic mutation profile of tumor specimen TCGA-43-A56U-01A (aliquot TCGA-43-A56U-01A-11D-A26M-08) from TCGA case TCGA-43-A56U, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 76.2 years (27,847 days).
Specimen TCGA-43-A56U-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf936d97-faea-423c-b2ca-4121eb158a82.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-43-A56U-10A (Blood Derived Normal), aliquot TCGA-43-A56U-10A-01D-A26K-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dd9d716e-34e1-4796-8b50-90e7e646fe06

The open-access MAF lists 275 somatic variants for this specimen: 200 protein-altering or splice-affecting, 70 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 173, Silent 70, Nonsense Mutation 21, Intron 4, Frame Shift Del 3, Splice Site 3, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.74761C>T p.R24921* (on ENST00000591111; = p.R17497* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | catalogued as rs869025545, CM1514737, COSV100604447; ClinVar: likely pathogenic; called by muse, mutect2
- ADGRB3 | c.2630C>G p.P877R | Missense Mutation (SNP) | VAF 15/154 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1198594350, COSV53245001, COSV53265652, COSV99484969; called by muse, mutect2, varscan2
- ADH1B | c.652G>C p.A218P | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs367812131; called by muse, mutect2
- ADRA1A | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99370874; called by muse, mutect2, varscan2
- AKAP11 | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 6/110 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99213897; called by muse, mutect2
- AKAP8 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.055); catalogued as rs947540357, COSV99511913; called by muse, mutect2, varscan2
- ALMS1 | c.3158G>T p.R1053M | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.917); catalogued as COSV52513996; called by muse, mutect2
- ANKRD13A | c.1441C>G p.Q481E | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.072); catalogued as COSV99923969; called by muse, mutect2
- APOBR | c.2921G>T p.W974L (on ENST00000431282; = p.W983L on NM_018690.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100112530; called by muse, mutect2
- APOBR | c.2922G>C p.W974C (on ENST00000431282; = p.W983C on NM_018690.4) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100112538; called by muse, mutect2
- ARFGEF1 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 8/114 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0.024); catalogued as COSV99142300; called by muse, mutect2
- ARID1A | c.1543C>T p.Q515* | Nonsense Mutation (SNP) | VAF 21/277 reads (8%) | catalogued as COSV61377807; called by muse, mutect2
- ASCC2 | c.1807G>A p.E603K | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as rs146488197; called by muse, mutect2, varscan2
- ATG2B | c.835C>G p.P279A | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100738002; called by muse, mutect2
- BCL10 | c.577C>A p.P193T | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100997798; called by muse, mutect2
- C1GALT1 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as COSV99777572; called by muse, mutect2, varscan2
- C8orf34 | c.609G>T p.L203F | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1370151349, COSV100446197; called by muse, mutect2, varscan2
- CD22 | c.416G>T p.R139M | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.423); catalogued as COSV99323200; called by muse, mutect2
- CDC42BPA | c.3857G>A p.R1286Q (on ENST00000334218 / NM_001366019.2; = p.R1273Q on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1329763799, COSV100505031; called by muse, mutect2, varscan2
- CDCP1 | c.2176C>T p.R726* | Nonsense Mutation (SNP) | VAF 22/200 reads (11%) | catalogued as COSV56103982; called by muse, mutect2, varscan2
- CDH5 | c.1262T>C p.V421A | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV100439226; called by mutect2, varscan2
- CDH8 | c.1754C>T p.P585L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.67); PolyPhen benign (0.316); catalogued as COSV100181429; called by muse, mutect2, varscan2
- CETN1 | c.250A>G p.I84V | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV100511315; called by muse, mutect2, varscan2
- CIB3 | c.283T>C p.F95L | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs557712754, COSV99521790; called by mutect2, varscan2
- CLASRP | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT tolerated (0.14); catalogued as COSV99673805; called by muse, mutect2, varscan2
- CLPTM1L | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.029); catalogued as rs1230641907, COSV100307067, COSV57992584; called by muse, mutect2, varscan2
- CSMD3 | c.10381G>T p.G3461* (on ENST00000297405 / NM_001363185.1; = p.G3292* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99833762; called by muse, mutect2
- CUL1 | c.1606A>G p.S536G | Missense Mutation (SNP) | VAF 21/213 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.062); catalogued as COSV100296652; called by muse, mutect2
- CYP4F12 | c.708C>G p.S236R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as COSV100215826; called by muse, mutect2, varscan2
- CYP4F3 | c.714G>T p.Q238H | Missense Mutation (SNP) | VAF 14/206 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV99658148; called by muse, mutect2
- DACH2 | c.1546C>A p.Q516K | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV64169462, COSV64184965; called by muse, mutect2
- DCC | c.2402A>G p.N801S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs1165355345, COSV100499945; called by muse, mutect2, varscan2
- DCLK1 | c.402A>G p.I134M | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.7); catalogued as COSV99711080; called by muse, mutect2
- DDX42 | c.1564G>T p.G522C | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs1302491831, COSV100834919; called by muse, mutect2
- DNAH17 | c.4810C>T p.R1604C | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs765608243, COSV67752523; called by mutect2, varscan2
- DNAH8 | c.4204A>C p.I1402L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100545117; called by muse, varscan2
- DNAH9 | c.707C>G p.S236C | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99305783; called by muse, mutect2, varscan2
- DNMBP | c.2035G>T p.G679C | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV100143723; called by muse, mutect2, varscan2
- DOCK8 | c.3695T>C p.F1232S | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.168); catalogued as COSV101209915; called by muse, mutect2
- DPAGT1 | c.1054G>A p.D352N | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV99597971; called by muse, mutect2
- DUSP12 | c.695C>G p.S232C | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV63411639, COSV63411716; called by muse, mutect2
- DUSP19 | c.586C>T p.Q196* | Nonsense Mutation (SNP) | VAF 7/90 reads (8%) | catalogued as COSV100700262; called by muse, mutect2
- E2F4 | c.1165G>A p.D389N | Missense Mutation (SNP) | VAF 30/225 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100681627; called by muse, mutect2, varscan2
- EGFR | c.575C>G p.P192R | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.063); catalogued as COSV99290842; called by muse, mutect2
- ENOX2 | c.1256A>T p.D419V (on ENST00000338144 / NM_001382520.1; = p.D390V on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100584119; called by muse, mutect2
- EPB42 | c.1759A>T p.R587* (on ENST00000441366 / NM_001114134.2; = p.R617* on NM_000119.3) | Nonsense Mutation (SNP) | VAF 6/92 reads (7%) | catalogued as COSV100281950; called by muse, mutect2
- FA2H | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs867338122, COSV54725832; called by mutect2, varscan2
- FAM135B | c.1779C>A p.S593R | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV52756674; called by muse, mutect2
- FAM47C | c.181G>T p.G61C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63728500; called by muse, mutect2, varscan2
- FAM83H | c.1356G>T p.Q452H | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV101186977; called by muse, mutect2, varscan2
- FBXO15 | c.1264-1G>T p.X422_splice | Splice Site (SNP) | VAF 9/106 reads (8%) | catalogued as COSV99503306; called by muse, mutect2
- FCHO1 | c.2285G>C p.G762A | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.083); catalogued as COSV53185475; called by muse, mutect2
- FCRL4 | c.514G>T p.D172Y | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV99619784; called by muse, mutect2, varscan2
- FERD3L | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51761976, COSV51764624; called by muse, mutect2
- FGD3 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 21/166 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV100490546; called by muse, mutect2, varscan2
- FLNC | c.1822A>G p.I608V | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as rs779240577, COSV100368080; called by mutect2, varscan2
- FLRT2 | c.855C>A p.N285K | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.69); catalogued as rs757165198, COSV100420375; called by muse, mutect2
- FUNDC2 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101045511; called by muse, mutect2, varscan2
- GK2 | c.1325T>C p.L442P | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100725949; called by muse, mutect2
- GOLGA4 | c.3457C>T p.L1153F | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.96); catalogued as COSV62710668; called by muse, mutect2
- GOLGB1 | c.7531G>C p.E2511Q | Missense Mutation (SNP) | VAF 15/185 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV100510821, COSV61469198; called by muse, mutect2
- GPR137B | c.300C>G p.F100L | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); catalogued as COSV63991071, COSV63991373; called by muse, mutect2
- GZF1 | c.2050G>A p.A684T | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.019); catalogued as COSV100582516; called by muse, mutect2, varscan2
- H2BC4 | c.106G>T p.E36* | Nonsense Mutation (SNP) | VAF 23/201 reads (11%) | catalogued as COSV100019753; called by muse, mutect2, varscan2
- HBS1L | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.76); PolyPhen benign (0.021); catalogued as COSV100892562; called by muse, mutect2, varscan2
- HCN1 | c.2120C>A p.P707H | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.87); catalogued as COSV100300173; called by muse, mutect2, varscan2
- HCN1 | c.2119C>A p.P707T | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.335); catalogued as COSV100300174, COSV57523217, COSV57527789; called by muse, mutect2, varscan2
- HIVEP1 | c.5743C>A p.Q1915K | Missense Mutation (SNP) | VAF 13/98 reads (13%) | SIFT tolerated (0.99); PolyPhen benign (0.043); catalogued as COSV101045121; called by muse, mutect2, varscan2
- IFIH1 | c.2243G>T p.G748V | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99718632; called by muse, mutect2, varscan2
- INSIG2 | c.340G>T p.V114F | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.428); catalogued as COSV99830523; called by muse, mutect2
- IRF3 | c.335C>G p.S112* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV99881084; called by muse, mutect2, varscan2
- ISM2 | c.514C>A p.P172T | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.54); catalogued as COSV99376623; called by muse, mutect2
- ITGAD | c.1176G>T p.M392I | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1451585075, COSV101210468; called by muse, mutect2
- JADE2 | c.1610C>T p.S537L | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV50921464; called by muse, mutect2, varscan2
- KDM4A | c.1954G>C p.E652Q | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.014); catalogued as COSV100969498; called by muse, mutect2
- KLF8 | c.280C>G p.P94A | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.777); catalogued as COSV63847688; called by muse, mutect2
- KMT2A | c.11251G>A p.E3751K | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.257); catalogued as rs1555052860, COSV100628794; called by muse, mutect2, varscan2
- LAMC3 | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143654398, COSV63094174; called by muse, mutect2, varscan2
- LIN28B | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as COSV100558803; called by mutect2, varscan2
- LMTK2 | c.3772G>T p.E1258* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV99806811; called by muse, mutect2
- MAGI1 | c.3153G>T p.K1051N (on ENST00000402939 / NM_001033057.2; = p.K1080N on NM_004742.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/117 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100440932; called by muse, mutect2
- MAP1LC3B2 | c.88A>T p.K30* | Nonsense Mutation (SNP) | VAF 11/151 reads (7%) | catalogued as COSV100186605; called by muse, mutect2
- MAP2 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.096); catalogued as COSV99559841; called by muse, mutect2, varscan2
- MCTP1 | c.1663G>A p.D555N | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.177); catalogued as rs998582409, COSV56529340; called by muse, mutect2, varscan2
- MGAT3 | c.831C>G p.F277L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100361872, COSV57868441; called by muse, mutect2
- MIER1 | c.1523A>C p.E508A (on ENST00000355356 / NM_001077701.3; = p.E525A on NM_020948.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.071); catalogued as COSV100590967; called by muse, mutect2, varscan2
- MKLN1 | c.1484T>C p.V495A | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as rs1312473100, COSV100759818; called by muse, mutect2
- MKRN3 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV100091118; called by muse, mutect2, varscan2
- MLXIPL | c.2082G>C p.Q694H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as COSV100515329, COSV57669485; called by muse, mutect2, varscan2
- MRPL2 | c.372G>C p.E124D | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV99431903; called by muse, mutect2
- MTR | c.389A>T p.E130V | Missense Mutation (SNP) | VAF 8/72 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV100856021; called by muse, mutect2
- MTRF1 | c.364G>C p.E122Q | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as COSV99520929; called by muse, mutect2, varscan2
- MUC16 | c.31055C>A p.T10352N | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV67474915; called by muse, mutect2, varscan2
- MUC16 | c.26800C>A p.L8934I | Missense Mutation (SNP) | VAF 11/172 reads (6%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.006); catalogued as rs1220325168, COSV101199872; called by muse, mutect2
- MYO3A | c.3121A>T p.K1041* | Nonsense Mutation (SNP) | VAF 4/35 reads (11%) | catalogued as COSV99779597; called by muse, mutect2
- N4BP2L1 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); catalogued as COSV100583055; called by muse, mutect2, varscan2
- NBPF3 | c.896C>G p.S299* | Nonsense Mutation (SNP) | VAF 18/224 reads (8%) | catalogued as COSV100558747, COSV59063538; called by muse, mutect2
- NCKAP5 | c.3191A>G p.Q1064R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100491918; called by muse, mutect2, varscan2
- NCSTN | c.2093T>G p.F698C | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99667132; called by muse, mutect2
- NDEL1 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.833); catalogued as COSV100232990; called by mutect2, varscan2
- NEK8 | c.1957G>T p.G653* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV99261875; called by muse, mutect2, varscan2
- NEUROD1 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV99716904; called by muse, mutect2
- NEUROD4 | c.484C>T p.L162F | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99669903; called by muse, mutect2
- NIT1 | c.111G>T p.M37I | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV100919087; called by muse, mutect2, varscan2
- NLRP4 | c.1701G>T p.K567N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV100016281; called by mutect2, varscan2
- NLRP8 | c.1216C>A p.L406M | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV99405251; called by muse, mutect2, varscan2
- NPR3 | c.1327G>C p.E443Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV99422931; called by muse, mutect2
- NUDT17 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100566783; called by muse, mutect2, varscan2
- NUP160 | c.3181G>C p.E1061Q | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV101021465; called by muse, mutect2
- NUP98 | c.3004G>A p.E1002K (on ENST00000359171 / NM_001365126.1; = p.E985K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.396); catalogued as COSV100262330; called by muse, mutect2, varscan2
- OGT | c.2382G>C p.Q794H | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV101035383; called by muse, mutect2
- OLFM3 | c.41C>G p.T14S | Missense Mutation (SNP) | VAF 6/74 reads (8%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); catalogued as COSV100129471; called by muse, mutect2
- OR13C9 | c.696G>T p.E232D | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.098); catalogued as COSV99403438, COSV99403514; called by muse, mutect2
- OR2G6 | c.121G>T p.G41W | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598139; called by muse, mutect2
- OR2L8 | c.43G>T p.G15W | Missense Mutation (SNP) | VAF 13/116 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61726605; called by muse, mutect2, varscan2
- OR3A2 | c.759C>A p.H253Q | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101375053; called by muse, mutect2
- OR6C70 | c.782C>G p.S261* | Nonsense Mutation (SNP) | VAF 4/71 reads (6%) | catalogued as COSV59244771; called by muse, mutect2
- OR7C2 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.308); catalogued as COSV99934513; called by muse, mutect2
- OR8A1 | c.224C>A p.S75Y | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as COSV99420554; called by muse, mutect2
- OR8D4 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 15/174 reads (9%) | catalogued as COSV100361811, COSV58431793; called by muse, mutect2
- ORC1 | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV100856660; called by muse, mutect2
- PARP2 | c.1718T>A p.L573* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as COSV99162649; called by muse, mutect2, varscan2
- PASD1 | c.598T>A p.S200T | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.282); catalogued as COSV100949350; called by muse, mutect2
- PCDH18 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV61271322; called by muse, mutect2
- PCDHB16 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.057); catalogued as COSV99502003; called by muse, mutect2, varscan2
- PCF11 | c.3137C>G p.P1046R | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.086); catalogued as COSV100018360; called by muse, mutect2, varscan2
- PCLO | c.10735C>A p.Q3579K | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV100432315; called by muse, mutect2, varscan2
- PDE4DIP | c.3770G>T p.G1257V | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs782524072, COSV100519063; called by muse, mutect2, varscan2
- PKHD1 | c.613C>A p.Q205K | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as COSV61873654; called by muse, mutect2
- PKHD1L1 | c.3611C>G p.T1204S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.124); catalogued as COSV101006094; called by mutect2, varscan2
- PPP1R15A | c.1505C>T p.A502V | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as COSV99566038; called by muse, mutect2
- PPP2R1A | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100436268; called by muse, mutect2, varscan2
- PPP4R3B | c.1782G>C p.M594I (on ENST00000616407 / NM_001122964.3; = p.M509I on NM_020463.4) | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as COSV99701986; called by muse, mutect2
- PRPSAP2 | c.826G>C p.D276H | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV99264518; called by muse, mutect2, varscan2
- PRSS53 | c.570C>G p.I190M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as COSV54922592, COSV99762282; called by muse, mutect2, varscan2
- PYGL | c.403G>A p.G135S | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746697171, COSV99368608, COSV99369082; called by muse, mutect2, varscan2
- RINT1 | c.937C>G p.L313V | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as COSV99994380; called by muse, mutect2
- RNF123 | c.1353G>T p.E451D | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.251); catalogued as COSV100570673; called by muse, mutect2, varscan2
- RNF38 | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen possibly damaging (0.811); catalogued as rs751793838, COSV99425034; called by muse, mutect2, varscan2
- RUFY2 | c.146T>A p.L49* | Nonsense Mutation (SNP) | VAF 6/48 reads (13%) | catalogued as COSV100700112; called by muse, mutect2, varscan2
- RYR2 | c.2076C>A p.H692Q | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100770026; called by muse, mutect2
- SAMD9L | c.2440C>G p.L814V | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100560672; called by muse, mutect2, varscan2
- SENP6 | c.2480T>A p.M827K | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.062); catalogued as COSV100894426, COSV64186968; called by muse, mutect2
- SHISA5 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs1231841738; called by muse, mutect2
- SLCO5A1 | c.2147G>T p.W716L | Missense Mutation (SNP) | VAF 16/200 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99479976; called by muse, mutect2
- SLITRK3 | c.1127G>T p.G376V | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.998); catalogued as COSV53854422, COSV99579204; called by muse, mutect2, varscan2
- SMTN | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100294316; called by muse, mutect2, varscan2
- SPATA31E1 | c.3481A>G p.M1161V | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1216330817; called by muse, mutect2
- SS18 | c.497C>G p.S166C | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as COSV99294142, COSV99294450; called by muse, mutect2
- ST14 | c.1551C>A p.N517K | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV99598741; called by muse, mutect2
- STXBP5L | c.2593A>T p.I865F | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV99874012; called by muse, mutect2
- SYT14 | c.1556G>T p.W519L | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99655270; called by muse, mutect2
- TBX18 | c.416C>T p.P139L | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1562268300, COSV63736111; called by muse, mutect2, varscan2
- TCHP | c.157G>C p.E53Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV100452570; called by muse, mutect2, varscan2
- TF | c.1046C>A p.T349K | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV99395729; called by muse, mutect2, varscan2
- TMEM117 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.201); catalogued as COSV99862578; called by muse, mutect2
- TMEM132E | c.976C>A p.R326S (on ENST00000321639; = p.R416S on NM_001304438.2) | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.522); catalogued as rs564573738; called by muse, mutect2, varscan2
- TMEM244 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.046); catalogued as COSV100933630; called by muse, mutect2
- TNFRSF14 | c.541C>T p.H181Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.071); catalogued as COSV100859138; called by muse, mutect2, varscan2
- TNFSF13 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as rs1167021681, COSV53433003; called by muse, mutect2
- TOP2B | c.3037C>G p.Q1013E (on ENST00000264331 / NM_001330700.2; = p.Q1008E on NM_001068.3) | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.3); catalogued as COSV99979673; called by muse, mutect2
- TPR | c.1919C>G p.S640* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100823916; called by muse, mutect2
- TRIP12 | c.4238G>A p.G1413D | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.381); catalogued as COSV99390200; called by muse, mutect2, varscan2
- TTC21B | c.1796G>C p.G599A | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV54631370, COSV99692282; called by muse, mutect2, varscan2
- UNC93A | c.708G>C p.K236N | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100023290, COSV57807260; called by muse, mutect2, varscan2
- VEGFC | c.518G>T p.C173F | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99709806; called by muse, mutect2, varscan2
- VN1R2 | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV59039218; called by muse, mutect2
- YTHDC2 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV99363272; called by muse, mutect2
- ZFYVE26 | c.6696G>C p.E2232D | Missense Mutation (SNP) | VAF 39/437 reads (9%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.607); catalogued as COSV100720396; called by muse, mutect2
- ZHX1 | c.2179C>G p.Q727E | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.675); catalogued as COSV99933846; called by muse, mutect2
- ZHX1 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as COSV99933656; called by muse, mutect2, varscan2
- ZHX3 | c.2434T>A p.F812I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100476020; called by muse, mutect2
- ZMYND8 | c.3172C>T p.H1058Y (on ENST00000311275 / NM_001363741.2; = p.H1032Y on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99520342; called by muse, mutect2, varscan2
- ZNF536 | c.2461C>A p.H821N | Missense Mutation (SNP) | VAF 8/93 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.054); catalogued as COSV100835216; called by muse, mutect2
- ZSWIM2 | c.1270C>A p.L424I | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.254); catalogued as COSV99719880, COSV99720018; called by muse, mutect2
- ZSWIM5 | c.1752G>C p.K584N | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.198); catalogued as COSV100655551; called by muse, mutect2, varscan2
- AREG | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 68/329 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- ASAH2 | c.1438T>A p.W480R | Missense Mutation (SNP) | VAF 13/162 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- B3GNT6 | c.672C>A p.D224E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- BEND2 | c.1990G>T p.G664* | Nonsense Mutation (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- BSDC1 | c.346G>A p.D116N | Missense Mutation (SNP) | VAF 5/76 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.257); called by muse, mutect2
- DENND3 | c.163A>G p.T55A | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2
- EMSY | c.3469G>T p.A1157S | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2
- EPB41L3 | c.2815A>G p.T939A | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- FYB1 | c.346A>T p.K116* | Nonsense Mutation (SNP) | VAF 4/72 reads (6%) | called by muse, mutect2
- GBP6 | c.1820T>A p.I607K | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2
- IGLV4-3 | c.358C>A p.Q120K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2
- IPO8 | c.24G>T p.Q8H | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2
- LAMA2 | c.3086del p.R1029Hfs*46 | Frame Shift Del (DEL) | VAF 12/72 reads (17%) | called by mutect2, pindel, varscan2
- MAP2K4 | c.997del p.E333Kfs*30 | Frame Shift Del (DEL) | VAF 9/53 reads (17%) | called by mutect2, pindel, varscan2
- MAP3K9 | c.1844+2T>C p.X615_splice | Splice Site (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
- NAPA | c.554A>G p.Y185C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); called by muse, mutect2
- PDE11A | c.583C>T p.H195Y | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- PRKCI | c.1686G>T p.Q562H | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, mutect2
- SEL1L2 | c.1105-1G>A p.X369_splice | Splice Site (SNP) | VAF 5/55 reads (9%) | called by muse, mutect2
- SIGLEC8 | c.1310C>A p.P437H | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.048); called by muse, mutect2
- SPATA31D1 | c.623del p.L208* | Frame Shift Del (DEL) | VAF 9/81 reads (11%) | called by mutect2, varscan2
- TEX37 | c.283A>T p.T95S | Missense Mutation (SNP) | VAF 4/82 reads (5%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.006); called by muse, mutect2
- UTP20 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- ZNF648 | c.1564C>T p.H522Y | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.725); called by muse, mutect2
- ABCA13 | c.9507C>T p.F3169= | Silent (SNP) | VAF 21/256 reads (8%) | catalogued as COSV101446943; called by muse, mutect2
- AHNAK | c.8775C>G p.V2925= | Silent (SNP) | VAF 10/200 reads (5%) | catalogued as COSV99947344; called by muse, mutect2
- APOB | c.1533G>C p.L511= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as rs1041952, COSV99265555; called by muse, mutect2, varscan2
- ARHGEF10L | c.1710C>G p.V570= | Silent (SNP) | VAF 16/164 reads (10%) | catalogued as COSV99392807; called by muse, mutect2
- ASAH2 | c.828T>C p.N276= | Silent (SNP) | VAF 6/58 reads (10%) | catalogued as rs1246173632; called by muse, mutect2
- ASL | c.1092C>T p.L364= | Silent (SNP) | VAF 13/192 reads (7%) | catalogued as COSV59189169; called by muse, mutect2
- BAHCC1 | c.489C>T p.F163= | Silent (SNP) | VAF 7/142 reads (5%) | called by muse, mutect2
- BMPR2 | c.2796C>G p.P932= | Silent (SNP) | VAF 5/92 reads (5%) | catalogued as COSV101001480; called by muse, mutect2
- CAMTA1 | c.3453C>T p.A1151= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV100349289; called by muse, mutect2, varscan2
- CCDC103 | c.534G>T p.L178= | Silent (SNP) | VAF 5/74 reads (7%) | catalogued as COSV99493283; called by muse, mutect2
- CD1E | c.111C>T p.F37= | Silent (SNP) | VAF 11/109 reads (10%) | catalogued as COSV100936997; called by muse, mutect2
- CHD4 | c.2322C>T p.I774= (on ENST00000357008 / NM_001363606.2; = p.I787= on NM_001273.5) | Silent (SNP) | VAF 5/88 reads (6%) | catalogued as COSV100538000; called by muse, mutect2
- CHODL | c.354C>T p.L118= | Silent (SNP) | VAF 4/80 reads (5%) | catalogued as COSV54735685; called by muse, mutect2
- CLSTN2 | c.2145C>G p.L715= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101515392, COSV101515701; called by muse, mutect2, varscan2
- CRY2 | c.1365G>A p.L455= | Silent (SNP) | VAF 4/46 reads (9%) | catalogued as COSV101314586; called by muse, mutect2
- CSDE1 | c.534G>C p.L178= (on ENST00000358528 / NM_001007553.3; = p.L147= on NM_007158.6) | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV99794942; called by muse, mutect2, varscan2
- CYP1A2 | c.696C>T p.S232= | Silent (SNP) | VAF 10/126 reads (8%) | catalogued as rs1212524834, COSV59659427; called by muse, mutect2
- EEF1A2 | c.1161G>T p.L387= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99419402; called by mutect2, varscan2
- EGF | c.2712A>G p.Q904= | Silent (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- EXTL1 | c.822C>T p.L274= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs956265965, COSV100959103; called by muse, mutect2, varscan2
- FADS6 | c.507G>A p.T169= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs767030840, COSV59603513; called by muse, mutect2, varscan2
- FAM135B | c.498G>T p.V166= | Silent (SNP) | VAF 17/126 reads (13%) | catalogued as COSV99357108; called by muse, mutect2, varscan2
- FNDC5 | c.516C>T p.F172= | Silent (SNP) | VAF 6/39 reads (15%) | catalogued as COSV100992486; called by muse, mutect2, varscan2
- FYB1 | c.951T>A p.P317= | Silent (SNP) | VAF 5/49 reads (10%) | catalogued as COSV60957590; called by muse, mutect2, varscan2
- GIMAP2 | c.117G>T p.G39= | Silent (SNP) | VAF 4/48 reads (8%) | catalogued as COSV56234392; called by muse, mutect2
- GPR18 | c.81C>G p.V27= | Silent (SNP) | VAF 12/108 reads (11%) | catalogued as COSV100540567; called by muse, varscan2
- GRIK3 | c.558C>A p.I186= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100901663; called by muse, mutect2
- GTF2I | c.780T>A p.T260= | Silent (SNP) | VAF 5/102 reads (5%) | catalogued as COSV100259620; called by muse, mutect2
- GTF2IRD1 | c.102C>G p.L34= | Silent (SNP) | VAF 5/50 reads (10%) | catalogued as rs374457609, COSV99734678; called by muse, mutect2
- H2AX | c.381G>A p.P127= | Silent (SNP) | VAF 4/68 reads (6%) | called by muse, mutect2
- HAL | c.828G>T p.P276= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as COSV54118523, COSV99701407; called by muse, mutect2
- HDC | c.733C>T p.L245= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1443689063, COSV99984013; called by muse, mutect2
- HDHD3 | c.690C>T p.I230= | Silent (SNP) | VAF 4/57 reads (7%) | catalogued as COSV99444927; called by muse, mutect2
- HTR3C | c.51C>A p.V17= | Silent (SNP) | VAF 10/74 reads (14%) | catalogued as COSV100570621; called by muse, mutect2, varscan2
- KCNK10 | c.897A>G p.L299= | Silent (SNP) | VAF 10/106 reads (9%) | catalogued as COSV100068293; called by muse, mutect2
- MCF2 | c.1534C>A p.R512= | Silent (SNP) | VAF 18/214 reads (8%) | catalogued as COSV100644761, COSV58482477; called by muse, mutect2
- MRPL44 | c.921C>T p.F307= | Silent (SNP) | VAF 6/67 reads (9%) | catalogued as COSV99285206; called by muse, mutect2, varscan2
- NEK7 | c.504C>T p.F168= | Silent (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- NLRP4 | c.117C>G p.L39= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV56708034; called by muse, mutect2
- NR0B1 | c.1122T>C p.S374= | Silent (SNP) | VAF 7/99 reads (7%) | catalogued as COSV100973521; called by muse, mutect2
- OR1S1 | c.939C>A p.A313= | Silent (SNP) | VAF 6/152 reads (4%) | called by muse, mutect2
- OR2M7 | c.69C>A p.T23= | Silent (SNP) | VAF 17/232 reads (7%) | catalogued as rs538250966, COSV58738759, COSV58740949; called by muse, mutect2
- OR4F6 | c.42C>T p.F14= | Silent (SNP) | VAF 9/80 reads (11%) | catalogued as COSV61026858; called by muse, mutect2, varscan2
- PIK3CB | c.1710A>G p.P570= | Silent (SNP) | VAF 36/144 reads (25%) | catalogued as rs762938623, COSV56685124; called by muse, mutect2, varscan2
- PKD1L1 | c.5118A>G p.P1706= | Silent (SNP) | VAF 8/78 reads (10%) | catalogued as COSV99219644; called by muse, mutect2
- PLAA | c.2374C>T p.L792= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV101263514; called by muse, mutect2, varscan2
- PNPO | c.573G>T p.R191= (on ENST00000225573; = p.R234= on NM_018129.4) | Silent (SNP) | VAF 11/66 reads (17%) | catalogued as COSV99846502; called by muse, mutect2, varscan2
- POTEE | c.855G>A p.Q285= | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV58227173; called by muse, mutect2
- PPP4R4 | c.702G>A p.R234= | Silent (SNP) | VAF 3/44 reads (7%) | called by muse, mutect2
- PRDM9 | c.2409C>A p.P803= | Silent (SNP) | VAF 17/164 reads (10%) | catalogued as COSV99690411; called by muse, varscan2
- QSOX1 | c.1620C>T p.I540= | Silent (SNP) | VAF 18/166 reads (11%) | catalogued as COSV100852869; called by muse, mutect2, varscan2
- RELN | c.9583C>T p.L3195= | Silent (SNP) | VAF 7/87 reads (8%) | catalogued as COSV100633655; called by muse, mutect2
- RIMBP2 | c.1059C>T p.L353= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as COSV99899436; called by muse, mutect2
- S100A13 | c.285C>T p.I95= | Silent (SNP) | VAF 14/161 reads (9%) | catalogued as COSV59884619; called by muse, mutect2
- SCN5A | c.2841C>T p.L947= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100348224; called by muse, mutect2, varscan2
- SELP | c.1929A>T p.P643= | Silent (SNP) | VAF 14/208 reads (7%) | catalogued as COSV99739859; called by muse, mutect2
- SEMA6C | c.993C>G p.V331= | Silent (SNP) | VAF 9/175 reads (5%) | catalogued as COSV100501295; called by muse, mutect2
- SLITRK1 | c.387G>A p.L129= | Silent (SNP) | VAF 13/84 reads (15%) | catalogued as rs1405853874, COSV100999946; called by muse, mutect2, varscan2
- STYXL2 | c.2646G>T p.V882= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- SUCNR1 | c.669T>C p.T223= | Silent (SNP) | VAF 11/145 reads (8%) | catalogued as rs993239338, COSV100751751; called by muse, mutect2
- SVEP1 | c.7065G>A p.L2355= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV52842538, COSV99928973; called by muse, mutect2, varscan2
- SZT2 | c.8352C>G p.P2784= (on ENST00000634258 / NM_001365999.1; = p.P2727= on NM_015284.4) | Silent (SNP) | VAF 5/66 reads (8%) | catalogued as COSV100987232; called by muse, mutect2
- TAAR5 | c.180C>T p.S60= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV99236892; called by muse, mutect2
- TAF2 | c.1419C>T p.F473= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV100978672; called by muse, mutect2, varscan2
- TCHH | c.2586G>A p.R862= | Silent (SNP) | VAF 12/125 reads (10%) | catalogued as rs781459279, COSV100915045; called by muse, mutect2
- TNPO2 | c.732G>C p.R244= | Silent (SNP) | VAF 4/50 reads (8%) | called by muse, mutect2
- UBR4 | c.9018C>T p.L3006= | Silent (SNP) | VAF 6/60 reads (10%) | catalogued as COSV100920751; called by muse, mutect2
- VIM | c.1237C>T p.L413= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as COSV99813085; called by muse, mutect2, varscan2
- ZNF574 | c.2247A>G p.T749= | Silent (SNP) | VAF 22/214 reads (10%) | catalogued as COSV99726103; called by muse, varscan2
- ZNF91 | c.1863G>A p.K621= | Silent (SNP) | VAF 7/59 reads (12%) | catalogued as COSV100322681; called by muse, mutect2, varscan2
- CR2 | c.1979-179G>A | Intron (SNP) | VAF 7/81 reads (9%) | catalogued as COSV100889637; called by muse, mutect2
- CSH2 | c.456+45T>A | Intron (SNP) | VAF 9/99 reads (9%) | catalogued as COSV100400214; called by muse, mutect2, varscan2
- LRRC27 | chr10:132331462 C>T | 5'Flank (SNP) | VAF 5/39 reads (13%) | catalogued as COSV100689774; called by mutect2, varscan2
- TTN | c.34264+584C>A | Intron (SNP) | VAF 16/242 reads (7%) | catalogued as COSV60180893; called by muse, mutect2
- TTN | c.10303+2347T>C | Intron (SNP) | VAF 6/52 reads (12%) | catalogued as COSV100611791; called by muse, mutect2, varscan2
